Somatic mutation profile of tumor specimen MP2PRT-PAUZNB-TMP1-A (aliquot MP2PRT-PAUZNB-TMP1-A-2-0-D-A79Q-36) from MP2PRT case MP2PRT-PAUZNB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,016 days).
Specimen MP2PRT-PAUZNB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97645e0a-30b1-4e96-ba44-19acb7058068.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUZNB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUZNB-NB1-A-1-0-D-A79Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/031a255a-b578-4646-966a-b1eb2978eda2

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 110/254 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNC2 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as rs762145266, COSV54367311; called by muse, mutect2, varscan2
- LSS | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 149/390 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs769378489, COSV62700980; called by muse, mutect2, varscan2
- OR52B4 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs766612100, COSV68768781; called by muse, mutect2, varscan2
- SNRNP70 | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 265/624 reads (42%) | catalogued as COSV99672108; called by muse, mutect2, varscan2
- FICD | c.976G>T p.D326Y | Missense Mutation (SNP) | VAF 178/411 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- NHSL1 | c.2202G>T p.E734D | Missense Mutation (SNP) | VAF 197/478 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SAMD5 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 222/508 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- IGHV3-23 | chr14:106268604 TGTC>CCT | Silent (DEL) | VAF 65/171 reads (38%) | called by pindel, varscan2*
